Somatic mutation profile of tumor specimen 0DAZP5 from CCDI case PBBITE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Brain stem; Age at diagnosis: 2.4 years (860 days).
Specimen 0DAZP5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb89aaac-6858-4a4f-a744-fe65fc38e88e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAZP6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6320bec5-eb47-4982-bf17-6617dccc52f0

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 16/608 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPANXN3 | c.141A>T p.S47= | Silent (SNP) | VAF 238/328 reads (73%) | catalogued as COSV65140134; called by muse, mutect2, varscan2
- CACNA1A | c.4602+74G>A | Intron (SNP) | VAF 62/160 reads (39%) | catalogued as rs1285832883; called by muse, mutect2, varscan2
